Somatic mutation profile of tumor specimen ALCH-ABEI-TTP1-A (aliquot ALCH-ABEI-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABEI, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.3 years (28,596 days).
Specimen ALCH-ABEI-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7fecc91-cf68-41df-b707-20b9a83e5dde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABEI-NB1-A (Blood Derived Normal), aliquot ALCH-ABEI-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3b5afe1-f70b-495b-a583-ea71ef122b93

The open-access MAF lists 47 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Intron 2, Splice Site 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 313/947 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADGRL3 | c.4509G>T p.E1503D (on ENST00000506720 / NM_001322402.2; = p.E1392D on NM_015236.6) | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.006); catalogued as COSV72229541, COSV72231416; called by muse, mutect2
- FBN1 | c.6901A>T p.I2301F | Missense Mutation (SNP) | VAF 58/646 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs1428185990; called by muse, mutect2
- HHIP | c.1449C>G p.F483L | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as COSV56837706; called by muse, mutect2
- IL22 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 81/1126 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60160311; called by muse, mutect2
- LAMB3 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs922467680; called by muse, mutect2
- PTPN14 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as rs368851967, COSV100872300; called by muse, mutect2
- RELN | c.4876G>A p.G1626S | Missense Mutation (SNP) | VAF 46/616 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs576837100, COSV100632930; called by muse, mutect2
- TTN | c.65186G>A p.G21729D (on ENST00000591111; = p.G14305D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/167 reads (6%) | PolyPhen probably damaging (1); catalogued as rs1372713604; called by muse, mutect2
- ZNF142 | c.4280G>A p.R1427H (on ENST00000411696 / NM_001379660.1; = p.R1227H on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/461 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs778416781, COSV101377033, COSV68745368; called by muse, mutect2
- ADAMTS17 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 16/463 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP6V0A4 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 62/388 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- CC2D2A | c.4022C>T p.T1341I | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- CFAP45 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 57/328 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DOCK8 | c.4582G>A p.A1528T | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- EGFL6 | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- FBN2 | c.2674+1G>A p.X892_splice | Splice Site (SNP) | VAF 46/618 reads (7%) | called by muse, mutect2
- FOXJ2 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRK4 | c.864A>T p.R288S (on ENST00000398052 / NM_182982.3; = p.R256S on NM_005307.3) | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- HDAC5 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 43/248 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HOXD11 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 50/392 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3A | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 30/450 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIC1 | c.2372C>A p.A791D | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SESN2 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 23/222 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC6A7 | c.1918C>T p.Q640* | Nonsense Mutation (SNP) | VAF 71/334 reads (21%) | called by muse, mutect2, varscan2
- TGOLN2 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 80/562 reads (14%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- TSPAN1 | c.21T>G p.I7M | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2
- WDR87 | c.3841C>T p.H1281Y | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ZNF528 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF549 | c.177C>A p.N59K (on ENST00000376233 / NM_001199295.2; = p.N46K on NM_153263.2) | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CDH12 | c.2235G>A p.G745= | Silent (SNP) | VAF 88/570 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.3408G>T p.L1136= (on ENST00000297405 / NM_001363185.1; = p.L1032= on NM_052900.3) | Silent (SNP) | VAF 24/582 reads (4%) | called by muse, mutect2
- DSG1 | c.549C>T p.D183= | Silent (SNP) | VAF 72/544 reads (13%) | catalogued as rs200895473; called by mutect2, varscan2
- FRY | c.1569C>T p.A523= | Silent (SNP) | VAF 29/383 reads (8%) | catalogued as rs373081011, COSV100968650; called by muse, mutect2
- GPR153 | c.1104G>T p.G368= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs1231699904; called by muse, mutect2
- GPR35 | c.351C>T p.A117= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs749560340; called by mutect2, varscan2
- GRIN2B | c.2064C>T p.N688= | Silent (SNP) | VAF 28/422 reads (7%) | catalogued as rs748606750, COSV74206340; called by muse, mutect2
- OR10G7 | c.489C>T p.F163= | Silent (SNP) | VAF 32/676 reads (5%) | catalogued as COSV57868895; called by muse, mutect2
- OR2G6 | c.90C>A p.I30= | Silent (SNP) | VAF 34/268 reads (13%) | catalogued as rs768357004; called by muse, mutect2, varscan2
- RANBP6 | c.2352C>T p.S784= | Silent (SNP) | VAF 47/306 reads (15%) | catalogued as rs1298240144, COSV52389541; called by muse, mutect2, varscan2
- SH3GL3 | c.831G>A p.K277= | Silent (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- SIDT2 | c.1497C>G p.A499= | Silent (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2, varscan2
- TUBB2B | c.423C>T p.G141= | Silent (SNP) | VAF 25/502 reads (5%) | called by muse, mutect2
- VIL1 | c.1053G>A p.A351= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as rs368301441, COSV50293710; called by muse, mutect2, varscan2
- NUMBL | c.249+31G>T | Intron (SNP) | VAF 18/182 reads (10%) | catalogued as rs1278203589; called by muse, mutect2
- SOHLH1 | c.-30C>A | 5'UTR (SNP) | VAF 12/134 reads (9%) | catalogued as rs897705765, COSV53681094; called by muse, mutect2
- TCF21 | c.451-16C>T | Intron (SNP) | VAF 30/523 reads (6%) | called by muse, mutect2
